Surgical pathology report (de-identified scan), TCGA case TCGA-B2-4101, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Christiana Healthcare, specimen TCGA-B2-4101-01A (Primary Tumor).

SPECIMEN

Left kidney

CLINICAL NOTES

PRE-OP DIAGNOSIS: Left renal mass

GROSS DESCRIPTION

The specimen is received unfixed labeled "left kidney" and consists of a radical nephrectomy specimen measuring 24 x 14 x 6.5 cm. The kidney itself measures 12 x 11 cm in greatest cross sectional dimension. On cut section there is a central yellow

and tan tumor in the kidney. The tumor measures 9.5 x 7.5 by approximately 4.5 cm. The adrenal gland is present. A portion of the tumor is taken for research purposes. Sections after fixation

Block summary: 1 - adrenal gland; 2 - margins of resection; 3-9 - tumor and adjacent normal kidney.

MICROSCOPIC DESCRIPTION

Tumor type: Clear cell type renal cell carcinoma

Tumor grade: 3 (out of 4; Fuhrman et al. AJSP 6:655,)

The tumor is mostly Fuhrman grades 1 and 2, but grade 3 change is seen in block #6.

Tumor size: 9.5 cm

Renal capsule: Negative for malignancy

Renal sinus: Negative for malignancy

Vascular invasion: Absent

Hilar margins: Negative for malignancy

Kidney away from tumor: Focal chronic interstitial inflammation

pTNM Stage: T2a

MICROSCOPIC DESCRIPTION

Adrenal gland: Normal

4
DIAGNOSIS

Kidney and adrenal gland, left, resection:

Clear cell type renal cell carcinoma, Fuhrman grade 3.

Source: NCI Genomic Data Commons file ba20db79-991b-4a91-b690-a755a2b1db11 (TCGA-B2-4101.4BF64CC4-EFD4-46EC-B0A9-EE1CE613EADC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).